Gene-level copy-number profile of tumor specimen HCM-SANG-1314-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1314-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1314-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d69a2f2f-fbb7-4f41-a235-ff2231b5142e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1314-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/7f680ad4-e7c1-4d5d-b819-6386fa956ecb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 10,229; copy number 2: 47,375; copy number 3: 398; copy number 4: 260; copy number 5: 258; copy number 6: 381.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr18:76,751,305–76,751,841, 1 gene: CCND3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 639 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:37,289,638–64,327,972, 639 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
